Gene-level copy-number profile of tumor specimen TCGA-36-2529-01A from TCGA case TCGA-36-2529, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.4 years (26,092 days).
Specimen TCGA-36-2529-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f043caa4-0483-42a6-8627-e161e1941695.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2529-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/51e1f128-3d0a-409d-abf9-7d193f69b1b2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 1,131; copy number 2: 16,832; copy number 3: 16,564; copy number 4: 15,512; copy number 5: 5,926; copy number 6: 1,635; copy number 7: 369; copy number 8: 763; copy number 9: 744; copy number 11: 16; copy number 12: 5; copy number 13: 35; copy number 14: 2; copy number 17: 41; copy number 18: 18; copy number 19: 111; copy number 24: 11; copy number 25: 34.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,149 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,862,175–240,475,187, 34 genes, copy number 8 (within-gene range 5–8): AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2.
- chr4:65,034,634–65,670,495, 6 genes, copy number 8 (within-gene range 6–8): AC107058.1, EFL1P2, AC096754.1, LINC02835, EPHA5, AC115223.1.
- chr4:69,437,357–70,532,743, 28 genes, copy number 8 (within-gene range 4–8): AC108078.3, AC108078.2, UGT2B4, UGT2A3P7, AC093829.1, UGT2A2, UGT2A1, SULT1B1, SULT1D1P, AC108941.3, SULT1E1, AC108941.1, CSN1S1, CSN2, STATH, HTN3, HTN1, CSN1S2AP, PRR27, ODAM, FDCSP, CSN3, CABS1, SMR3A, SMR3B, OPRPN, MUC7, AMTN.
- chr4:72,280,969–76,802,426, 94 genes, copy number 7–9 (broad region; genes not listed).
- chr7:51,016,212–53,947,804, 29 genes, copy number 11–24 (within-gene range 3–24): COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854.
- chr8:105,929,126–145,066,685, 579 genes, copy number 8 (broad region; genes not listed).
- chr11:54,591,480–54,725,816, 11 genes, copy number 7: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr12:9,641,723–11,171,608, 74 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr12:15,107,783–20,136,163, 62 genes, copy number 13–17 (broad region; genes not listed).
- chr12:21,354,959–26,421,462, 85 genes, copy number 8–25 (within-gene range 5–25) (broad region; genes not listed).
- chr12:26,335,864–26,373,733, 2 genes, copy number 17: AC055720.2, RNA5SP354.
- chr14:18,333,726–24,115,010, 418 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr19:12,576,100–20,758,952, 453 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr19:29,083,094–31,417,794, 40 genes, copy number 7 (within-gene range 6–7): AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2.
- chr19:36,259,540–37,614,179, 55 genes, copy number 7: LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571.
- chr19:39,030,436–40,950,660, 111 genes, copy number 19 (broad region; genes not listed).
- chr20:17,226,107–18,744,216, 43 genes, copy number 9–18 (within-gene range 3–18): PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2, AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1.
- chr20:18,592,330–18,643,634, 3 genes, copy number 9: RN7SL638P, RNU6ATAC34P, DUXAP7.
- chr20:19,756,390–20,712,644, 14 genes, copy number 9 (within-gene range 3–9): AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2.
- chr21:20,651,450–21,797,415, 8 genes, copy number 8–12: LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425.

Autosomal genes at a single copy (total copy number 1): 733. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
